Somatic mutation profile of tumor specimen TCGA-3B-A9HP-01A (aliquot TCGA-3B-A9HP-01A-11D-A387-09) from TCGA case TCGA-3B-A9HP, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 57.8 years (21,094 days).
Specimen TCGA-3B-A9HP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a97d6df-1ecd-441f-bbd6-787e4f06aa96.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3B-A9HP-10A (Blood Derived Normal), aliquot TCGA-3B-A9HP-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6bbfdc49-61bd-4650-af47-1df942c3b190

The open-access MAF lists 41 somatic variants for this specimen: 35 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 5, Nonsense Mutation 4, Frame Shift Del 3, Splice Site 3, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FANK1 | c.10C>T p.Q4* | Nonsense Mutation (SNP) | VAF 8/75 reads (11%) | hotspot (GDC flag); catalogued as rs202109621, COSV64160606; called by muse, varscan2
- TP53 | c.376-1G>A p.X126_splice | Splice Site (SNP) | VAF 14/21 reads (67%) | hotspot (GDC flag); catalogued as rs868137297, CS1313555, COSV52688618, COSV52749979, COSV52994579, COSV52996344; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- ADGRF3 | c.496A>G p.T166A (on ENST00000311519 / NM_001145168.1; = p.T107A on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100275429; called by muse, mutect2, varscan2
- CCDC116 | c.686C>A p.T229N | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.68); catalogued as rs908266768, COSV99489009; called by muse, mutect2
- CNNM2 | c.1510G>A p.D504N | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as COSV100881760; called by muse, mutect2, varscan2
- COL4A1 | c.903+1G>A p.X301_splice | Splice Site (SNP) | VAF 28/78 reads (36%) | catalogued as rs1363290269, COSV65423731; called by muse, mutect2, varscan2
- CORIN | c.103T>G p.S35A | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.079); catalogued as COSV99904452; called by muse, mutect2, varscan2
- CTAG2 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.072); catalogued as rs782161068, COSV55994250; called by muse, mutect2, varscan2
- DENND11 | c.428G>C p.S143T | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV101530730; called by muse, mutect2, varscan2
- GATB | c.1410G>A p.Q470= | Splice Region (SNP) | VAF 6/45 reads (13%) | catalogued as COSV99859324; called by muse, mutect2
- GPR156 | c.1960G>A p.V654I | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100251715; called by muse, mutect2, varscan2
- KCNA1 | c.883C>G p.R295G | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1366571577, COSV101230361, COSV66838375; called by muse, mutect2, varscan2
- LCE2C | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs780048858, COSV64228585; called by muse, mutect2, varscan2
- MUC17 | c.2559del p.S854Afs*14 | Frame Shift Del (DEL) | VAF 29/89 reads (33%) | catalogued as COSV60279818, COSV60291102; called by mutect2, pindel, varscan2
- NANOG | c.913G>T p.V305L | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs745903026; called by muse, mutect2, varscan2
- NLRP9 | c.1921A>G p.S641G | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV100243445; called by mutect2, varscan2
- RABGAP1L | c.358C>A p.P120T | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.434); catalogued as COSV52283482, COSV99274087; called by muse, varscan2
- RALGAPB | c.770T>A p.F257Y | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV99485805; called by muse, mutect2, varscan2
- RB1 | c.1150C>T p.Q384* | Nonsense Mutation (SNP) | VAF 19/35 reads (54%) | catalogued as CM942037, COSV57311318; called by muse, mutect2, varscan2
- RRP8 | c.1154+1G>A p.X385_splice | Splice Site (SNP) | VAF 4/42 reads (10%) | catalogued as COSV99601825, COSV99602057; called by muse, mutect2
- RYR1 | c.2455C>T p.R819* | Nonsense Mutation (SNP) | VAF 20/47 reads (43%) | catalogued as rs193922774, CM081776, COSV100615674, COSV100616994; ClinVar: not provided; called by muse, mutect2, varscan2
- RYR2 | c.12920G>A p.R4307H | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as rs769146715, COSV63684322, COSV63691311; called by muse, mutect2, varscan2
- SCN1A | c.4002G>C p.R1334S (on ENST00000303395 / NM_001202435.3; = p.R1323S on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100322096; called by muse, mutect2, varscan2
- SLC16A9 | c.952A>C p.I318L | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as COSV101264483; called by muse, mutect2, varscan2
- SLC8A3 | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374224410; called by muse, mutect2, varscan2
- TAAR6 | c.50A>T p.N17I | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.15); catalogued as COSV99256908; called by muse, mutect2
- TBC1D3F | c.292G>C p.A98P | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs1209773846; called by muse, mutect2, varscan2
- TBKBP1 | c.495G>T p.L165F | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100659238; called by muse, mutect2
- TJP2 | c.3346G>A p.D1116N | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as rs1198157853, COSV99601829; called by muse, mutect2, varscan2
- TNC | c.3902A>G p.N1301S | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs766134463, COSV100406261; called by muse, mutect2, varscan2
- TULP3 | c.262G>T p.G88C | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101237619; called by muse, mutect2, varscan2
- VPS35L | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 22/46 reads (48%) | catalogued as COSV99221716; called by muse, mutect2, varscan2
- ZNF691 | c.181G>A p.G61S (on ENST00000372502; = p.G30S on NM_015911.3) | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100996152; called by muse, mutect2, varscan2
- KRT14 | c.1091del p.G364Vfs*13 | Frame Shift Del (DEL) | VAF 12/89 reads (13%) | called by mutect2, pindel, varscan2
- TM4SF18 | c.38del p.L13Cfs*2 | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | called by mutect2, pindel, varscan2
- ATP10A | c.4119G>A p.V1373= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV100791534; called by muse, mutect2, varscan2
- C12orf45 | c.21C>G p.P7= | Silent (SNP) | VAF 55/135 reads (41%) | catalogued as rs539464433, COSV99774053; called by muse, mutect2, varscan2
- POLA1 | c.2436T>C p.P812= | Silent (SNP) | VAF 24/244 reads (10%) | catalogued as COSV100985785; called by muse, mutect2
- SMARCA4 | c.2742G>T p.L914= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV100759110; called by muse, mutect2
- WSCD2 | c.207C>T p.D69= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs771811964, COSV99775233; called by muse, mutect2, varscan2
- MIR519A2 | n.17T>C | RNA (SNP) | VAF 46/121 reads (38%) | called by muse, mutect2, varscan2
